Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4774, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4774-01A (Primary Tumor).

[page 1 of 3]
Ref. Source:

Clinical Diagnosis & History:

Right renal mass.

Specimens Submitted:

- 1: SP: Kidney, right renal mass, partial nephrectomy
- 2: SP: Kidney, right cyst, excision
- 3: SP: Kidney, right cyst wall, excision

DIAGNOSIS:

- 1. SP: Kidney, right renal mass, partial nephrectomy
Tumor Type: Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:
Nuclear grade II/IV

Tumor Size:
Greatest diameter is 3.6 cm.

Local Invasion (for renal cortical types):
Not identified

Renal Vein Invasion:
Not identified

Surgical Margins:
Tumor present at renal parenchymal margin

Non-Neoplastic Kidney:
Unremarkable

Adrenal Gland:
Not identified

Lymph Nodes:
Not identified

Staging for renal cell carcinoma/oncocytoma:
pT1 Tumor <= 7.0 cm in greatest dimension limited to the kidney

- 2. SP: Kidney, right cyst, excision
Benign renal cortical cyst.

[page 2 of 3]
3. SP: Kidney, right cyst wall, excision [REDACTED]

Benign renal parenchyma.

Gross Description:

1) The specimen is received fresh for frozen section, labeled "Right Renal Mass". It consists of a partial nephrectomy specimen measuring 4.6 x 3.9 x 3.1 cm. The specimen is oriented with a black stitch labeled as "base of tumor margin", which is inked black. The specimen is serially sectioned to reveal a fairly well-circumscribed, tan-pink to golden yellow mass measuring 3.6 x 2.4 x 3.3 cm. Grossly at the deep resection margin the adjacent renal parenchyma is tan-maroon and grossly unremarkable. Tissue is submitted for TPS. Sections are submitted.

Summary of Sections:

FSC - frozen section control (deep margin)

MAS - tumor representative

CAP - capsule

ADJ - adjacent

2) The specimen is received fresh for frozen section, labeled "Right Renal Cyst". It consists of a piece of flat, tan-red soft tissue measuring 2.5 x 1.3 x 0.4 cm. The entire specimen is submitted.

Summary of Sections:

FSC - frozen section control

REM - remainder of the specimen

3) The specimen is received fresh for frozen section, labeled "Right Renal Cyst Wall". It consists of a piece of tan-red soft tissue measuring 0.5 x 0.4 x 0.2 cm. The entire specimen is submitted in one block.

Summary of Sections:

FSC - frozen section control

Summary of Sections:

Part 1: SP: Kidney, right renal mass, partial nephrectomy [REDACTED] [REDACTED])

Block	Sect. Site	PCs
1	ADJ	1
1	CAP	1
1	FSC	1
4	MASS	4

Part 2: SP: Kidney, right cyst, excision [REDACTED]

Block	Sect. Site	PCs
1	FSC	1
1	REM	1

Part 3: SP: Kidney, right cyst wall, excision [REDACTED] [REDACTED]

Block	Sect. Site	PCs
1	FSC	1

[page 3 of 3]
Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: RENAL CELL CARCINOMA, FOCALLY PRESENT AT THE MARGIN. [REDACTED]
PERMANENT DIAGNOSIS: Same.
- 2) FROZEN SECTION DIAGNOSIS: BENIGN CYST. [REDACTED]
PERMANENT DIAGNOSIS: Same.
- 3) FROZEN SECTION DIAGNOSIS: BENIGN. [REDACTED]
PERMANENT DIAGNOSIS: Same.
- [REDACTED]

Source: NCI Genomic Data Commons file 2bb824c7-c7f7-49a5-a048-f453fed57b86 (TCGA-BP-4774.599AA434-B593-4ADF-88E9-CF3F10F71EC2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).